Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5584, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5584-01A (Primary Tumor).

[page 1 of 2]
TISSUE DESCRIPTION:

Right kidney (285 grams, 12.0 x 9.0 x 6.0 cm), right periaortic tissue (aggregating 4.0 x 4.0 x 1.9 cm), right retroperitoneal lymph node, and anterior vena cava lymph node

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 3 (of 4) renal cell carcinoma, clear cell type, forms a 6.0 x 4.5 x 4.0 cm mass located in the mid pole. The tumor extends into the peripheral perinephric fat. A tumor thrombus is present in the renal vein. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative. No renal hilar lymph nodes are identified. The adrenal gland is present and unremarkable. A separate 4.0 x 4.0 x 4.0 cm benign cyst is present in the inferior pole.

Soft tissue, right periaortic, excision: Metastatic grade 3 (of 4) renal cell carcinoma, clear cell type.

Lymph node, right retroperitoneal, excision: One (of 1) lymph node shows metastatic grade 3 (of 4) renal cell carcinoma, clear cell type.

Lymph node, anterior vena cava,, excision: One (of 1) lymph node shows metastatic grade 3 (of 4) renal cell carcinoma, clear cell type.

[page 2 of 2]
Surgical Pathology

TISSUE DESCRIPTION:

Right kidney (285 grams, 12.0 x 9.0 x 6.0 cm), right periaortic tissue (aggregating 4.0 x 4.0 x 1.9 cm), right retroperitoneal lymph node, and anterior vena cava lymph node

DIAGNOSIS:

Kidney, right, radical nephrectomy: Grade 3 (of 4) renal cell carcinoma, clear cell type, forms a 6.0 x 4.5 x 4.0 cm mass located in the mid pole. The tumor extends into the peripheral perinephric fat. A tumor thrombus is present in the renal vein. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative. No renal hilar lymph nodes are identified. The adrenal gland is present and unremarkable. A separate 4.0 x 4.0 x 4.0 cm benign cyst is present in the inferior pole.

Soft tissue, right periaortic, excision: Metastatic grade 3 (of 4) renal cell carcinoma, clear cell type.

Lymph node, right retroperitoneal, excision: One (of 1) lymph node shows metastatic grade 3 (of 4) renal cell carcinoma, clear cell type.

Lymph node, anterior vena cava, excision: One (of 1) lymph node shows metastatic grade 3 (of 4) renal cell carcinoma, clear cell type.

Source: NCI Genomic Data Commons file ca313a3d-ca84-43a7-9e54-433986c2ffc6 (TCGA-CW-5584.7293FD54-12CF-4B54-BE83-EAE6DADDA483.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).